Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7604, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7604-01A (Primary Tumor).

Microscopic Description:

Sections demonstrate a moderately hypercellular glial neoplasm that diffusely infiltrates the parenchyma. The tumor has a prominent myxoid and microcystic architecture. The principle tumor cells resemble fibrillary astrocytes, but minor populations of small gemistocytes as well as cells with perinuclear halos are also seen. There is generally mild atypia with a few scattered moderately atypical nuclei. Mitotic figures are not seen. There is no microvascular proliferation or necrosis.

Addendum Description:

MIB-1 activity is highly variable within the tumor. In the most proliferative regions, a labeling index of 10.4% is calculated. In these areas, an occasional mitosis, which was not noted on the H&E sections, is also seen. This labeling index is significantly higher than expected in a grade II astrocytoma. Nevertheless, the overall histologic features do not warrant classification as anaplastic grade III. Based on the high proliferation activity, it is possible that this tumor is undergoing early anaplastic progression and close clinical follow up is warranted.

Addendum Diagnosis:

Consistent with well differentiated Astrocytoma (WHO Grade II). Consistent with well differentiated Astrocytoma (WHO Grade II).

MIB-1 Labeling Index= 10.4%

Source: NCI Genomic Data Commons file 9b10a90e-c9ca-43e3-a61a-041ff413a64f (TCGA-HT-7604.ECAC7160-5404-42F2-90D3-C43D1B8BB747.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).